FM case AD4971 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/e290af2c-c6a1-457b-a1ad-60b4982ca00e

Female, 46.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the ovary; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
